Somatic mutation profile of tumor specimen TCGA-QR-A70Q-01A (aliquot TCGA-QR-A70Q-01A-13D-A35D-08) from TCGA case TCGA-QR-A70Q, project TCGA-PCPG (Pheochromocytoma and Paraganglioma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Extra-adrenal paraganglioma, NOS; Tissue or organ of origin: Thorax, NOS; Age at diagnosis: 33.9 years (12,394 days).
Specimen TCGA-QR-A70Q-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 9b768816-6b94-46c4-82f1-cb18287bcd0c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-QR-A70Q-10A (Blood Derived Normal), aliquot TCGA-QR-A70Q-10A-01D-A35B-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a2655c0c-69c6-4a33-9da3-b31741b4ecab

The open-access MAF lists 8 somatic variants for this specimen: 7 protein-altering or splice-affecting, 1 silent.
By variant classification: Missense Mutation 6, Splice Site 1, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- DPPA4 | c.390+2T>C p.X130_splice | Splice Site (SNP) | VAF 4/86 reads (5%) | catalogued as rs1216921245; called by muse, mutect2
- WDR33 | c.599C>T p.A200V | Missense Mutation (SNP) | VAF 20/172 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV59256824; called by muse, mutect2, varscan2
- CCT4 | c.1415A>G p.N472S | Missense Mutation (SNP) | VAF 48/151 reads (32%) | SIFT tolerated (0.1); PolyPhen benign (0.072); called by muse, mutect2, varscan2
- COG5 | c.506T>C p.I169T | Missense Mutation (SNP) | VAF 6/63 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.702); called by muse, mutect2
- DEFB112 | c.230T>A p.I77N | Missense Mutation (SNP) | VAF 13/87 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.808); called by muse, mutect2, varscan2
- PPP1R13L | c.275G>C p.G92A | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.06); called by muse, mutect2, varscan2
- TMC1 | c.1644T>G p.C548W | Missense Mutation (SNP) | VAF 10/256 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); called by muse, mutect2
- GRM4 | c.354G>A p.Q118= | Silent (SNP) | VAF 2/16 reads (13%) | called by muse, mutect2
